Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1BM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1BM-01A (Primary Tumor).

100-0-3
Carcinoma, squamous cell, Nos 807013
Site Code: Cervix, Nos C53.9

12/29/10
hr

Name: [REDACTED]
Address: [REDACTED]
MR No.: [REDACTED]
Service: GYNECOLOGY
Surgeon: [REDACTED]

rg. Path. No.: [REDACTED]
DOB: [REDACTED]
Sex/Race: [REDACTED]
Location: [REDACTED]
Hosp. No.: [REDACTED]
Taken/Received: [REDACTED]

DIAGNOSIS

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA
- TUMOR INVOLVES THE ENDOCERVICAL CANAL, AND LOWER UTERINE SEGMENT BY DIRECT EXTENSION
- TUMOR INVOLVES THE POSTERIOR VAGINAL CUFF MARGIN OF RESECTION
- TUMOR MEASURES 0.1 CM TO THE NEAREST INKED POSTERIOR SOFT TISSUE MARGIN OF RESECTION
- LYMPHOVASCULAR INVASION IDENTIFIED

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA BY DIRECT EXTENSION

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA BY DIRECT EXTENSION

SOFT TISSUE, PARAMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA BY DIRECT EXTENSION

OVARY, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- BENIGN SIMPLE CYST

FALLOPIAN TUBE, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- BENIGN PARATUBAL CYSTS

VAGINA, "INTERIOR VAGINAL MARGIN," EXCISION
- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA BY DIRECT EXTENSION, WITH TUMOR IDENTIFIED AT THE SUTURED DISTAL MARGIN EDGE

LYMPH NODE, LEFT EXTERNAL, EXCISION
- METASTATIC MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA IN 1 OF 4 LYMPH NODES
- EXTRACAPSULAR EXTENSION IDENTIFIED

LYMPH NODES, LEFT OBTURATOR, EXCISION
- NO EVIDENCE OF MALIGNANCY IN 3 LYMPH NODES (0/3)

LYMPH NODES, RIGHT EXTERNAL, EXCISION
- NO EVIDENCE OF MALIGNANCY IN 5 LYMPH NODES (0/5)

Source: NCI Genomic Data Commons file 747029dd-c922-4c5e-9fd9-70363be8dce3 (TCGA-C5-A1BM.D23DE232-F930-40C8-A560-4B75C41C6115.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).